Surgical pathology report (de-identified scan), TCGA case TCGA-HD-8314, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-HD-8314-01A (Primary Tumor).

[page 1 of 2]
Final Diagnosis

Base of tongue, excision (FSA1 and FSA2):

Invasive squamous cell carcinoma, poorly differentiated, with basaloid features, excision complete.

Size of neoplasm: 1.7 cm in greatest dimensions.

No associated squamous cell carcinoma in situ identified.

Angiolymphatic invasion: Present.

Perineural invasion: Not identified.

New lateral margin:

Negative for neoplasm.

Left level 5:

Abundant adipose tissue with scant lymphoid tissue, negative for neoplasm.

Left level 4:

Sixteen (1) lymph nodes, negative for neoplasm.

Left level 3:

One (1) of twenty (20) lymph nodes involved by poorly differentiated squamous cell carcinoma.

Poorly differentiated squamous cell carcinoma involving soft tissue.

Left level 2B:

Eight (8) lymph nodes, negative for neoplasm.

Poorly differentiated squamous cell carcinoma involving soft tissue.

Comment: AJCC stage T1,N1 with

involvement by poorly differentiated squamous cell carcinoma of left neck soft tissue.

Clinical Information

[page 2 of 2]
[REDACTED]

Tongue cancer.

Frozen Section Diagnosis

Base of tongue (FSA1, FSA2):
Squamous cell carcinoma.
Margins clear. [REDACTED]

Gross Description

"FSA1." All frozen section control tissue is submitted in "FSA1".

"FSA2." All frozen section control tissue is submitted in "FSA2".

"NFSA." The specimen consists of a previously sectioned pink-tan soft tissue fragment which upon reconstruction measures approximately 3.5 x 2.4 x 2.4 cm. The specimen has been previously been inked by the pathologist as follows: 12:00-3:00 orange, 3:00-6:00 green, 6:00-12:00 yellow, and deep margin black. Previous sectioning reveals a 1.1 x 1.2 x 1.2 cm, pale tan, firm, well circumscribed mass within the medial one half aspect of the specimen. This grossly appears to come within less than a mm of the medial and deep margin and 1.5 cm of the superior half of the lateral margin and 1.7 cm of the inferior half of the lateral margin. "A1-A3," mass to include 3:00, 9:00, and deep margin; "A4," random sections of the inferior half of the specimen; "A5," 6:00 margin, representative.

"Additional lateral margin." The specimen consists of a 1.9 x 0.8 x 0.5 cm, tan-brown, irregular, soft tissue fragment. A stitch has been placed at the superior margin. One margin contains purple ink. This will be overlaid with black ink and the remaining specimen is inked orange. "B1," superior one half specimen; "B2," inferior one half specimen; all.

"Left level 5." The specimen consists of a 1 cm, yellow-tan fatty fragment. On examination, definite lymphoid tissue is not identified. All tissue is submitted in "C".

"Left level 4." The specimen consists of a 5.7 x 3.8 x 1.4 cm, yellow-tan fatty fragment. On examination, nineteen possible lymph nodes are identified. These range in size from 0.4-1.0 cm. "D1-D3," possible lymph nodes, representative.

"Left level 3." The specimen consists of a 7.1 x 4 x 3 cm, yellow-tan fatty fragment. On examination, twenty two possible lymph nodes are identified. These range in size from 0.3-3.8 cm. "E1-E3," possible lymph nodes, representative.

"Left level 2b." The specimen consists of a 3.5 x 3 x 2 cm, tan-brown, fatty, firm fragment. On examination, eight possible lymph nodes are identified. These range in size from 0.5-2.8 cm. "F1-F2," possible lymph nodes, representative. [REDACTED]

[REDACTED]

Performing Lab

[REDACTED]

Source: NCI Genomic Data Commons file 39356ead-5063-4f5f-8373-399b3993fd68 (TCGA-HD-8314.B9C245AC-7857-4CAE-9E8B-6A4F189F3604.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).